CCDI case PBCICY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e0eb60a4-c648-482a-bd3b-47f07366d467

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.1 years (3,315 days).

Biospecimens (3 samples)
- Sample 0DSG20: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSG2H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DSG2O: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
